Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5098, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5098-01A (Primary Tumor).

AL DIAGNOSIS

- 1: RIGHT KIDNEY, ALLOGRAFT NEPHRECTOMY -
- A. CHRONIC ALLOGRAFT NEPHROPATHY, SEVERE, WITH CALCIFIC GRAFT ATHEROSCLEROSIS.
- B. ACUTE REJECTION, MILD TO MODERATE, WITH LYMPHOID HYPERPLASIA.

- PART 2: RIGHT NATIVE KIDNEY, RADICAL NEPHRECTOMY -
- A. RENAL CELL CARCINOMA (4.0 CM.), GRANULAR AND CLEAR CELL TYPE, FUHRMAN'S NUCLEAR GRADE III, WITH FOCAL INVOLVEMENT OF PELVI-CALYCEAL SYSTEM; SURGICAL RESECTION MARGINS FREE OF TUMOR; NO VASCULAR INVASION SEEN; T1,NX,MX, G3,.
- B. SEPARATE LOW GRADE RENAL CELL NEOPLASM (0.3 CM.) WITH FOCAL PAPILLARY ARCHITECTURE.
- C. END-STAGE RENAL DISEASE WITH MULTIPLE CYSTS SHOWING FOCAL HEMORRHAGE.

Source: NCI Genomic Data Commons file 5aa505f8-fb62-4d62-8bce-565d24e497e8 (TCGA-B0-5098.C83BEBCF-5746-4269-8966-678B9B6B560A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).